Somatic mutation profile of tumor specimen MP2PRT-PATIIB-TMP1-A (aliquot MP2PRT-PATIIB-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATIIB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,616 days).
Specimen MP2PRT-PATIIB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4745cfc6-18ee-489d-ad24-9a2412f86a00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATIIB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATIIB-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b41b3f95-e49f-4a88-8d5e-fc358cb5bcf5

The open-access MAF lists 10 somatic variants for this specimen: 3 protein-altering or splice-affecting, 7 silent.
By variant classification: Silent 7, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 74/311 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HEG1 | c.2645C>T p.S882L | Missense Mutation (SNP) | VAF 169/486 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752436571; called by muse, mutect2, varscan2
- ARF6 | c.142A>G p.N48D | Missense Mutation (SNP) | VAF 157/640 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL5A1 | c.294G>A p.E98= | Silent (SNP) | VAF 93/232 reads (40%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2655G>A p.V885= (on ENST00000402739 / NM_001282597.3; = p.V837= on NM_004389.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 108/259 reads (42%) | catalogued as rs758165128, COSV58142696; called by muse, mutect2, varscan2
- DLG2 | c.1584C>T p.S528= | Silent (SNP) | VAF 125/347 reads (36%) | catalogued as rs138430783, COSV54683626, COSV54687593; called by muse, mutect2, varscan2
- GJA1 | c.888T>A p.S296= | Silent (SNP) | VAF 156/374 reads (42%) | called by muse, mutect2, varscan2
- GREB1 | c.828C>T p.N276= | Silent (SNP) | VAF 187/508 reads (37%) | catalogued as rs150918268; called by muse, mutect2, varscan2
- LIMCH1 | c.843C>T p.P281= | Silent (SNP) | VAF 211/664 reads (32%) | catalogued as rs761374389, COSV100573447, COSV58297570; called by muse, mutect2, varscan2
- OBSCN | c.13338C>T p.G4446= | Silent (SNP) | VAF 198/442 reads (45%) | catalogued as rs375469279; called by muse, varscan2
